TCGA case TCGA-2Y-A9H9 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/efc3e5e4-0d8e-4bef-a259-29f8ed21684f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Alive.

Diagnoses (3)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 70.3 years (25,670 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin; Days to treatment start: 281 days; Embolic agent: Other.
   Treatment given: Treatment type: Chemoembolization; Days to treatment start: 400 days (1.1 years).
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin; Days to treatment start: 434 days (1.2 years); Embolic agent: Spherical Particles.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sorafenib Tosylate; Days to treatment start: 1,017 days (2.8 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 70.4 years (25,729 days); Days to diagnosis: 59 days; Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 72.2 years (26,371 days); Days to diagnosis: 701 days (1.9 years); Prior treatment: Yes.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 59 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Liver; Days to recurrence: 59 days.
- Days to follow up: 456 days (1.2 years); Disease response: With Tumor.
- Days to follow up: 697 days (1.9 years); Disease response: With Tumor.
- Day 701 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 701 days (1.9 years).
- ECOG performance status: 0.

Molecular and laboratory tests
- Alpha Fetoprotein 12 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 7].
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.2].
- Platelets 203 (unit not recorded by GDC) [Blood test normal range lower: 143; Blood test normal range upper: 382].
- Prothrombin Time 11 Seconds [Blood test normal range lower: 8.3; Blood test normal range upper: 11.5].
- Albumin 4.7 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Total Bilirubin 0.6 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1.3].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 88 kg; Height: 178 cm; BMI: 27.8.
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption / Hepatitis C Infection.

Family history
- Relatives with cancer history count: 2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2Y-A9H9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-2Y-A9H9-01A-02-TS2: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 96; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 3; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2Y-A9H9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2Y-A9H9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Multiple.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment: Pharmaceutical therapy drug name: Naxavar.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: No.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: Yes.
- Ablations, Ablation, Embolization treatments, Embolization treatment 1: Embolizing agent utilized: LC Beads.
- Ablations, Ablation, Embolization treatments, Embolization treatment 3: Embolization therapy drug name: lipiodol/doxyrubicin; Embolizing agent utilized: embospheres.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 697 days; disease-specific survival: no event (censored), 697 days; disease-free interval: event (new tumor event after initially disease-free), 59 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 59 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2Y-A9H9-01A-21D-A38W-01): tumor purity 0.88, ploidy 2.07, whole-genome doublings 0.
